Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A29C, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A29C-06A (Metastatic).

DOB/Age/Sex
Location:
Requested by:
Requested on:
Specimen Rcvd:
Accession No.:
Copies to:

HISTOPATHOLOGY REPORT

REFERRED MRN

1CD-0-3

CLINICAL DETAILS

Recurrent melanoma (R) axilla. Tumour Bank. Fresh sterile specimen.

Melanoma, NOS 8720/3
Site: Axilla, NOS C44.5

MACROSCOPIC DESCRIPTION

(Dr

for 4/2/11

"RIGHT AXILLA MELANOMA". Specimen received in two halves post tumour banking. An unorientated skin ellipse, 40 x 19mm, with underlying tissue to a depth of 33mm. On sectioning there is a variegated pigmented subcutaneous nodule to a maximum diameter of 24mm. Full face of nodule embedded in blocks A to C with superficial portion of nodule bisected in A and deep bisected and embedded in blocks B & C. On two of the sections there appears to be a separate nodule 5 x 6mm present in two of the slices. Separate nodule in close proximity to larger nodule embedded in block D.

MICROSCOPIC REPORT

Sections show two subcutaneous deposits of malignant melanoma. Fine granular brown cytoplasm pigment is noted within scattered tumour cells. The tumour abuts on the underlying skeletal muscle. The lines of resection appear clear of the tumour (lateral by 1mm and deep by 2mm). No lymphovascular or perineural invasion is identified. The overlying epidermis is not involved.

SUMMARY

Right axilla: malignant melanoma.

REPORTED BY: A/Prof.

Dual/Synchronous: Primary Noted		

This

Source: NCI Genomic Data Commons file 6ccf733e-2d6a-4542-bf06-d1396d6b5dab (TCGA-EE-A29C.9358D777-DE2E-4AE2-937D-AC2D922CD848.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).